Gene-level copy-number profile of tumor specimen TCGA-N9-A4Q8-01A from TCGA case TCGA-N9-A4Q8, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IA; Age at diagnosis: 69.0 years (25,185 days).
Specimen TCGA-N9-A4Q8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.40b12018-6a80-4123-bf77-50375e76e687.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N9-A4Q8-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a6e36026-500e-4e74-a40b-208488754797

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 380; copy number 2: 2,223; copy number 3: 8,545; copy number 4: 16,249; copy number 5: 11,483; copy number 6: 12,908; copy number 7: 3,429; copy number 8: 1,340; copy number 9: 961; copy number 10: 256; copy number 11: 34; copy number 12: 1,618; copy number 13: 61; copy number 16: 11; copy number 17: 18; copy number 18: 31; copy number 22: 15; copy number 26: 50; copy number 30: 25; copy number 31: 63; copy number 34: 21; copy number 37: 27; copy number 47: 15; copy number 50: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N9-A4Q8-01A-31D-A28Q-01): tumor purity 0.84, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,228,595–8,424,648, 4 genes (within-gene range 0–2): FAM86B3P, ALG1L13P, PRAG1, AC103957.1.
- chr8:12,719,132–15,766,649, 35 genes (within-gene range 0–2): MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1, MIR383, AC084838.1, AC103851.1, TUSC3, AC100850.1.
- chr13:48,232,612–48,303,661, 2 genes: ITM2B, RB1-DT.
- chr13:48,316,863–48,341,330, 3 genes: PPP1R26P1, PCNPP5, AL392048.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,213 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:33,081,104–34,165,842, 20 genes, copy number 9 (within-gene range 5–9): AZIN2, AL662907.1, TRIM62, AL662907.2, AL662907.3, ZNF362, AL513327.2, A3GALT2, AL513327.1, PHC2, MIR3605, RN7SKP16, PHC2-AS1, TLR12P, ZSCAN20, AC115285.1, CSMD2, HSPD1P14, HMGB4, CSMD2-AS1.
- chr1:43,164,175–43,270,936, 1 gene, copy number 10 (within-gene range 8–10): EBNA1BP2.
- chr1:43,172,330–43,254,358, 1 gene, copy number 10 (within-gene range 8–10): CFAP57.
- chr1:43,269,983–47,997,385, 170 genes, copy number 10 (broad region; genes not listed).
- chr1:71,081,324–72,753,772, 9 genes, copy number 9 (within-gene range 5–9): ZRANB2-AS2, AL358453.1, NEGR1, AL354949.1, AL359821.1, NEGR1-IT1, GDI2P2, AL513166.1, RPL31P12.
- chr1:73,104,792–90,855,253, 257 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr1:113,073,198–113,685,923, 7 genes, copy number 9 (within-gene range 6–9): LRIG2, RLIMP2, AL357055.1, AL357055.2, MAGI3, AL391058.1, MTND5P20.
- chr1:115,641,970–115,768,714, 2 genes, copy number 9: VANGL1, CASQ2.
- chr1:203,765,177–204,494,724, 29 genes, copy number 9 (within-gene range 6–9): LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B.
- chr2:64,817,378–65,432,637, 18 genes, copy number 9: RN7SL341P, Y_RNA, AC007880.1, LINC01800, LINC02245, RN7SL211P, RPL11P1, SLC1A4, RNU6-548P, LINC02576, CEP68, RAB1A, SNORA74, AC007318.1, VDAC2P5, ACTR2, SPRED2, AC012370.1.
- chr2:65,439,838–65,555,534, 5 genes, copy number 9: AC012370.2, DNAJB12P1, RPS15AP15, RN7SL635P, VTRNA2-2P.
- chr3:73,382,431–74,136,892, 10 genes, copy number 9: PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1, AC108725.1, LINC02005, Metazoa_SRP, LINC02047, AC016930.1, AKR1B1P2.
- chr3:167,864,773–179,240,093, 159 genes, copy number 16–50 (broad region; genes not listed).
- chr6:43,450,352–44,155,519, 30 genes, copy number 9 (within-gene range 7–9): DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B.
- chr8:29,048,494–34,039,104, 95 genes, copy number 12 (within-gene range 2–12) (broad region; genes not listed).
- chr8:34,228,439–34,346,731, 1 gene, copy number 11 (within-gene range 1–11): AC090993.1.
- chr8:34,322,992–34,323,642, 1 gene, copy number 11: RPL10AP3.
- chr8:40,530,590–145,066,685, 1,617 genes, copy number 12–22 (within-gene range 2–22) (broad region; genes not listed).
- chr12:24,704,503–28,581,511, 91 genes, copy number 30–47 (broad region; genes not listed).
- chr14:27,258,717–30,573,629, 35 genes, copy number 9 (within-gene range 6–9): AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2, RNU11-5P, PRKD1, AL356756.1, RNU6-1234P, AL355053.1, AL133372.3, AL133372.2, AL133372.1, AL079305.1, G2E3-AS1, AL117355.1.
- chr14:73,275,107–74,262,738, 44 genes, copy number 9 (within-gene range 6–9): NUMB, AC005280.3, AC005280.2, AC005280.1, HEATR4, RIOX1, AC005225.1, AC005225.3, ACOT1, NT5CP2, AC005225.2, ACOT2, NT5CP1, AC005225.4, ACOT4, ACOT6, NDUFB8P1, DNAL1, RNU6-240P, AC006146.1, PNMA1, MIDEAS, MIR4505, AC005520.2, LINC02274, AC005520.4, PTGR2, AC005520.1, Y_RNA, AC005520.5, ZNF410, AC005480.1, AC005520.3, Y_RNA, FAM161B, COQ6, ENTPD5, AC005480.2, BBOF1, ALDH6A1, LIN52, RN7SL530P, AC006349.1, VSX2.
- chr17:4,710,596–5,078,113, 36 genes, copy number 9 (within-gene range 5–9): ARRB2, MED11, AC091153.4, CXCL16, ZMYND15, TM4SF5, VMO1, AC233723.2, GLTPD2, PSMB6, AC233723.1, PLD2, MINK1, ATP6V0CP1, RN7SL784P, CHRNE, C17orf107, GP1BA, SLC25A11, RNF167, PFN1, ENO3, SPAG7, CAMTA2, AC004771.3, MIR6864, MIR6865, AC004771.1, AC004771.4, AC004771.2, INCA1, KIF1C, KIF1C-AS1, SLC52A1, AC012146.1, AC012146.2.
- chr19:10,391,133–11,079,426, 32 genes, copy number 11: CDC37, MIR1181, PDE4A, KEAP1, AC011461.1, S1PR5, ATG4D, RNU7-140P, MIR1238, KRI1, CDKN2D, AP1M2, AC011475.1, SLC44A2, ILF3-DT, ILF3, QTRT1, DNM2, MIR638, MIR4748, MIR199A1, MIR6793, TMED1, C19orf38, HIKESHIP2, CARM1, YIPF2, TIMM29, SMARCA4, AC011442.1, RN7SL192P, AC006127.1.
- chr19:44,725,984–46,196,218, 84 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr20:45,791,954–64,313,132, 459 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 380. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
